Gene-level copy-number profile of tumor specimen TCGA-23-2645-01A from TCGA case TCGA-23-2645, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 54.1 years (19,758 days).
Specimen TCGA-23-2645-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.dbe990e4-3dac-451c-85ec-6975ee9a6140.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-23-2645-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b06a2501-3d59-4802-b681-364c09186c17

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 5,423; copy number 2: 19,433; copy number 3: 18,722; copy number 4: 9,063; copy number 5: 3,563; copy number 6: 1,939; copy number 7: 915; copy number 8: 581; copy number 9: 61; copy number 11: 98.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-23-2645-01A-01D-1043-01): tumor purity 0.74, ploidy 3.11, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:150,584–264,703, 11 genes: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7,157 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–33,657,460, 578 genes, copy number 5–6 (broad region; genes not listed).
- chr2:33,722,721–34,069,550, 3 genes, copy number 6: MYADML, SLC25A5P2, LINC01318.
- chr3:4,749,192–7,790,482, 28 genes, copy number 5: EGOT, AC018816.2, AC018816.1, BHLHE40-AS1, BHLHE40, RNF10P1, UBTFL8, Y_RNA, AC090955.1, ARL8B, AC026202.2, AC026202.3, EDEM1, MIR4790, RN7SL553P, AC026202.1, AC087857.1, AC026167.1, AC027119.1, AC069277.1, GRM7-AS3, AC069277.2, GRM7, MRPS36P1, GRM7-AS2, AC066585.1, GRM7-AS1, AC077690.1.
- chr3:101,163,094–101,861,022, 25 genes, copy number 5: ACTR3P3, IMPG2, SENP7, ZNF90P1, AC110994.1, AC110994.2, Y_RNA, FAM172BP, TRMT10C, PCNP, AC073861.1, AC084198.1, RNU6-1256P, Y_RNA, Y_RNA, ZBTB11, RNY1P12, ZBTB11-AS1, RPL24, AC084198.2, PDCL3P4, CEP97, NXPE3, AC020651.1, NFKBIZ.
- chr3:117,672,154–171,460,408, 941 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr4:34,120,090–34,335,351, 1 gene, copy number 5 (within-gene range 3–5): LINC02484.
- chr4:34,657,606–43,588,097, 142 genes, copy number 5 (broad region; genes not listed).
- chr4:56,907,876–58,118,070, 19 genes, copy number 5: REST, AC069307.1, NOA1, POLR2B, RNU6-998P, IGFBP7, UBE2CP3, IGFBP7-AS1, AC111197.1, AC105390.1, RPS26P24, LINC02380, AC013724.1, AC107396.1, AC093725.2, AC093725.1, AC104790.1, SRIP1, AC096725.1.
- chr4:59,150,924–68,376,505, 93 genes, copy number 5 (broad region; genes not listed).
- chr4:126,431,694–190,092,279, 857 genes, copy number 5–8 (broad region; genes not listed).
- chr5:58,198–23,329,892, 380 genes, copy number 5–6 (broad region; genes not listed).
- chr7:49,850,421–63,263,456, 218 genes, copy number 7 (broad region; genes not listed).
- chr8:41,426,655–43,363,518, 64 genes, copy number 5 (broad region; genes not listed).
- chr8:56,917,084–145,066,685, 1,364 genes, copy number 5–11 (broad region; genes not listed).
- chr10:26,664,206–47,619,480, 399 genes, copy number 5 (broad region; genes not listed).
- chr12:66,767–32,396,147, 816 genes, copy number 5–8 (broad region; genes not listed).
- chr12:32,477,382–68,451,663, 920 genes, copy number 5–6 (broad region; genes not listed).
- chr15:40,300,670–40,316,634, 3 genes, copy number 5: PLCB2-AS1, AC020658.1, AC020658.2.
- chr18:1,254,383–1,408,344, 4 genes, copy number 5 (within-gene range 2–5): LINC00470, RN7SKP72, AP005119.1, AP005119.2.
- chr18:22,586,465–24,161,600, 31 genes, copy number 5 (within-gene range 3–5): RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA, CABLES1, TMEM241, AC011731.1, RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA, ANKRD29, RPS10P27, LAMA3, RPL23AP77, AC010754.1, TTC39C, TTC39C-AS1, AC090772.2, AC090772.1, RNU5A-6P, AC090772.4, CABYR.
- chr18:42,743,227–57,738,603, 226 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr20:23,160,857–24,666,616, 45 genes, copy number 5 (within-gene range 4–5): RNA5SP478, AL118508.1, AL390037.1, NXT1-AS1, NXT1, LINC01431, GZF1, NAPB, RNA5SP479, CSTL1, CST11, AL096677.1, Y_RNA, CST12P, AL109954.1, AL109954.2, CST8, CST13P, CST9LP1, CST9L, CST9LP2, CST9, CST3, AL121894.2, AL121894.1, AL121894.3, CST4, CST2P1, AL591074.2, CST1, CSTP2, AL591074.1, CST2, CST5, CSTP1, AL133466.1, GGTLC1, POM121L3P, LINC01721, AL110503.1, RNU1-23P, AL158090.1, GAPDHP53, SYNDIG1, AL157413.1.

Autosomal genes at a single copy (total copy number 1): 3,002. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
